Somatic mutation profile of tumor specimen TCGA-G2-AA3C-01A (aliquot TCGA-G2-AA3C-01A-21D-A391-08) from TCGA case TCGA-G2-AA3C, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 66.4 years (24,267 days).
Specimen TCGA-G2-AA3C-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 76f887b0-336c-4089-a769-50c729f18469.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G2-AA3C-10A (Blood Derived Normal), aliquot TCGA-G2-AA3C-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d5735df9-a61e-4063-907c-bccd752a53a1

The open-access MAF lists 278 somatic variants for this specimen: 200 protein-altering or splice-affecting, 70 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 171, Silent 70, Nonsense Mutation 15, Splice Site 4, Splice Region 3, Frame Shift Del 3, Frame Shift Ins 3, 5'UTR 2, RNA 2, 3'Flank 2, 5'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 25/62 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- NFE2L2 | c.242G>C p.G81A | Missense Mutation (SNP) | VAF 28/121 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67960014, COSV67960167, COSV67960618; called by muse, mutect2, varscan2
- ABCA2 | c.2211G>C p.M737I (on ENST00000614293; = p.M707I on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/37 reads (68%) | SIFT tolerated (0.07); PolyPhen benign (0.138); catalogued as rs1452881499, COSV55799080; called by muse, mutect2, varscan2
- ABCF1 | c.5C>T p.P2L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs529428649, COSV58228206; called by muse, varscan2
- ADAM21 | c.199T>G p.F67V | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as COSV50789668; called by muse, mutect2, varscan2
- ADAMTS18 | c.3015G>T p.K1005N | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.698); catalogued as COSV51401267; called by muse, mutect2, varscan2
- ADD1 | c.195+1G>A p.X65_splice | Splice Site (SNP) | VAF 3/25 reads (12%) | catalogued as rs1433097983, COSV99296983; called by muse, mutect2
- ADGRG6 | c.3155G>A p.G1052D | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51588395, COSV51590699; called by muse, mutect2, varscan2
- AKNA | c.1879G>A p.G627S | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.31); PolyPhen benign (0.011); catalogued as rs558018170, COSV56311634; called by muse, mutect2, varscan2
- AL592490.1 | c.2110C>T p.Q704* | Nonsense Mutation (SNP) | VAF 35/87 reads (40%) | catalogued as COSV101308284; called by muse, mutect2, varscan2
- AL592490.1 | c.1067C>T p.T356I | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.052); catalogued as rs1300460940, COSV69425267; called by muse, mutect2, varscan2
- ALMS1 | c.8212G>A p.E2738K | Missense Mutation (SNP) | VAF 36/139 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52502621; called by muse, mutect2, varscan2
- ALMS1 | c.8604G>C p.K2868N | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); catalogued as COSV52505391; called by muse, mutect2, varscan2
- ALPP | c.955C>T p.R319C | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as rs753036535, COSV67395940; called by mutect2, varscan2
- AMER3 | c.1006G>C p.D336H | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.3); catalogued as COSV58465723; called by muse, mutect2, varscan2
- APLP2 | c.559C>G p.L187V | Missense Mutation (SNP) | VAF 59/218 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as COSV53839623; called by muse, mutect2, varscan2
- ARHGAP21 | c.2956G>C p.E986Q | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100256664; called by muse, mutect2, varscan2
- ARHGEF6 | c.569C>T p.T190I | Missense Mutation (SNP) | VAF 47/90 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); catalogued as COSV51688628; called by muse, mutect2, varscan2
- ATG2A | c.607G>T p.E203* | Nonsense Mutation (SNP) | VAF 4/10 reads (40%) | catalogued as rs1223580964, COSV101034792; called by muse, varscan2
- ATG9A | c.188T>G p.L63R | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV60132528; called by muse, mutect2, varscan2
- ATG9A | c.187C>A p.L63I | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.096); catalogued as COSV60132531; called by muse, mutect2, varscan2
- AURKB | c.232G>C p.E78Q | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.293); catalogued as COSV60243921; called by muse, mutect2, varscan2
- BEND6 | c.274C>T p.R92* | Nonsense Mutation (SNP) | VAF 34/143 reads (24%) | catalogued as rs1052954048, COSV66070514; called by muse, mutect2, varscan2
- BPTF | c.3624C>G p.I1208M | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV58833679; called by muse, mutect2, varscan2
- BPTF | c.4994C>T p.S1665L | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV58833714; called by muse, mutect2, varscan2
- BRSK2 | c.1274T>G p.L425R | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.797); catalogued as COSV57541426; called by muse, mutect2, varscan2
- C11orf24 | c.608G>C p.R203T | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.105); catalogued as COSV58505193; called by muse, mutect2, varscan2
- C11orf24 | c.378G>C p.M126I | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV100422707; called by muse, mutect2
- C2CD2L | c.1020G>A p.L340= | Splice Region (SNP) | VAF 4/11 reads (36%) | catalogued as COSV100371492; called by muse, mutect2, varscan2
- CAPN9 | c.871G>C p.D291H | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55231657; called by muse, mutect2, varscan2
- CDH12 | c.1394G>C p.S465T | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.251); catalogued as COSV66394116; called by muse, mutect2, varscan2
- CEP97 | c.2338C>G p.Q780E | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as COSV59123398; called by muse, mutect2, varscan2
- CES2 | c.61C>G p.L21V | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.219); catalogued as rs775034770, COSV100399437, COSV57696523; called by muse, mutect2, varscan2
- CES4A | c.710C>T p.S237L | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.153); catalogued as rs373745989; called by muse, mutect2, varscan2
- CHRNA4 | c.899C>T p.S300L | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64718793; called by muse, mutect2, varscan2
- CIT | c.4492C>T p.P1498S | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT tolerated (0.35); PolyPhen benign (0.018); catalogued as rs865775936, COSV55863546, COSV55884568; called by muse, mutect2, varscan2
- CNKSR2 | c.1475C>A p.T492K | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as COSV54251908, COSV54252237; called by muse, mutect2, varscan2
- CNR1 | c.1012G>C p.D338H | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62986730, COSV62989184; called by muse, mutect2, varscan2
- COL11A2 | c.2326C>T p.R776C (on ENST00000341947 / NM_080680.3; = p.R669C on NM_080679.2) | Missense Mutation (SNP) | VAF 45/65 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs776701792, COSV59493332; called by muse, mutect2, varscan2
- COL4A4 | c.1096A>T p.K366* | Nonsense Mutation (SNP) | VAF 6/22 reads (27%) | catalogued as COSV100307703; called by muse, mutect2, varscan2
- COL5A3 | c.2448G>C p.E816D | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.207); catalogued as COSV53407975; called by muse, mutect2, varscan2
- CR2 | c.623C>T p.P208L | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65506479; called by muse, mutect2, varscan2
- CRISPLD1 | c.681C>A p.C227* | Nonsense Mutation (SNP) | VAF 9/26 reads (35%) | catalogued as rs1388348225, COSV100082446, COSV51543853; called by muse, mutect2, varscan2
- CSMD2 | c.7603G>T p.E2535* | Nonsense Mutation (SNP) | VAF 12/41 reads (29%) | catalogued as rs1227961701, COSV99592249, COSV99595207; called by muse, mutect2, varscan2
- CSMD3 | c.1943G>A p.G648E (on ENST00000297405 / NM_001363185.1; = p.G544E on NM_052900.3) | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52131683; called by muse, mutect2, varscan2
- CTNNA1 | c.331T>C p.F111L | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769342340, COSV57071159; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTNNA2 | c.1386C>T p.V462= | Splice Region (SNP) | VAF 8/37 reads (22%) | catalogued as COSV58141777; called by muse, mutect2, varscan2
- CYP11B2 | c.1315C>T p.H439Y | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs370517494, CM087154; called by muse, varscan2
- CYP2C9 | c.389C>T p.T130M | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200965026, CM062573, CM1412017, COSV53247414; called by muse, mutect2, varscan2
- DDI1 | c.1129G>C p.D377H | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as COSV56371802, COSV56376921; called by muse, mutect2, varscan2
- DDX58 | c.731G>A p.R244K | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV65882631; called by muse, mutect2, varscan2
- DENND2C | c.1474G>C p.E492Q (on ENST00000393274 / NM_001256404.2; = p.E435Q on NM_198459.4) | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.077); catalogued as COSV67920452; called by muse, mutect2, varscan2
- DIAPH2 | c.839C>T p.S280F | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61261300, COSV61263823; called by muse, mutect2, varscan2
- DMBT1 | c.1781C>T p.S594L | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as COSV57537894; called by muse, mutect2, varscan2
- DNAH9 | c.10117G>A p.E3373K | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.117); catalogued as COSV52340258, COSV52342807; called by muse, mutect2, varscan2
- DNAJB14 | c.372G>C p.L124F | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100508623; called by muse, mutect2
- DNAJC13 | c.6091A>G p.T2031A | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs769998417, COSV53447544; called by muse, mutect2, varscan2
- EIF4G2 | c.50C>T p.S17L | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.885); catalogued as rs1442776478, COSV101151049, COSV60596497; called by muse, mutect2, varscan2
- ELOA2 | c.1630C>T p.L544F | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as rs1196066458, COSV55295362, COSV55310392; called by muse, mutect2, varscan2
- EML5 | c.1003C>T p.P335S | Missense Mutation (SNP) | VAF 41/129 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.938); catalogued as rs866086610, COSV61343194; called by muse, mutect2, varscan2
- ERBB2 | c.1238C>T p.S413L | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as COSV54063885, COSV99507637; called by muse, varscan2
- FADD | c.626G>C p.*209Sext*38 | Nonstop Mutation (SNP) | VAF 9/35 reads (26%) | catalogued as COSV100096752; called by muse, mutect2
- FIGN | c.1682G>C p.G561A | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.88); PolyPhen probably damaging (0.914); catalogued as COSV100292978; called by muse, mutect2
- FMO4 | c.295G>C p.D99H | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.438); catalogued as rs1244787278, COSV63000749; called by muse, mutect2, varscan2
- FOLH1 | c.1533G>C p.R511S | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV57049280, COSV99923931; called by mutect2, varscan2
- FPR1 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs1286930729, COSV59051334; called by muse, mutect2, varscan2
- FRAS1 | c.9424C>T p.L3142F | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); catalogued as rs968093, COSV53597591; called by muse, mutect2, varscan2
- FRYL | c.1184G>A p.R395Q | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs781407347, COSV51942736; called by muse, mutect2, varscan2
- GDNF | c.299C>G p.P100R | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV58478753; called by muse, mutect2, varscan2
- GIGYF2 | c.1580C>A p.P527Q | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as rs1419432175, COSV101004580, COSV65247607; called by muse, varscan2
- GIGYF2 | c.1636C>T p.Q546* | Nonsense Mutation (SNP) | VAF 13/57 reads (23%) | catalogued as COSV101004601; called by muse, varscan2
- GIMAP1 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV56187190; called by muse, mutect2, varscan2
- GLI3 | c.1701G>C p.L567F | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as COSV67886464; called by muse, mutect2, varscan2
- GNAI3 | c.1045A>C p.K349Q | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.164); catalogued as COSV63983395; called by muse, mutect2, varscan2
- GPR158 | c.3031G>T p.V1011F | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as COSV66267089, COSV66281105; called by muse, mutect2, varscan2
- GPT2 | c.895G>C p.D299H | Missense Mutation (SNP) | VAF 50/177 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60837807; called by muse, mutect2, varscan2
- GSPT2 | c.88G>T p.D30Y | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.191); catalogued as COSV61213884; called by muse, mutect2, varscan2
- HOXB6 | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53312334, COSV99494440; called by muse, mutect2, varscan2
- HPR | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV57182018; called by muse, mutect2, varscan2
- HPX | c.1057C>T p.H353Y | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as COSV56418812; called by muse, mutect2, varscan2
- ITSN2 | c.3507C>G p.I1169M | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.283); catalogued as rs749035374, COSV61944918; called by muse, mutect2, varscan2
- KCNAB3 | c.751C>G p.P251A | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1017484081, COSV58140119; called by muse, mutect2, varscan2
- KITLG | c.527G>C p.R176T | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV57200567; called by muse, mutect2, varscan2
- KLHDC2 | c.886G>T p.D296Y | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53586814; called by muse, mutect2, varscan2
- KLHDC7B | c.1120G>A p.E374K (on ENST00000395676; = p.E1015K on NM_138433.5) | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.56); PolyPhen benign (0.024); catalogued as rs745950415, COSV67464341; called by muse, mutect2, varscan2
- KRT38 | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.399); catalogued as COSV55845561; called by muse, mutect2, varscan2
- LAMA1 | c.2428G>T p.D810Y | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.663); catalogued as COSV67533728; called by muse, mutect2, varscan2
- LAMA4 | c.42G>A p.W14* | Nonsense Mutation (SNP) | VAF 4/18 reads (22%) | catalogued as COSV54570490, COSV99683882; called by muse, mutect2
- LLGL2 | c.3058G>C p.E1020Q (on ENST00000392550 / NM_001031803.2; = p.Q1005H on NM_004524.3) | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.537); catalogued as COSV51344330, COSV51352495; called by muse, mutect2, varscan2
- LRRC14B | c.1497C>G p.F499L | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.104); catalogued as COSV57256357; called by muse, mutect2, varscan2
- MAGEA10 | c.255G>C p.Q85H | Missense Mutation (SNP) | VAF 49/77 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV54883359; called by muse, mutect2, varscan2
- MARCHF11 | c.1102C>A p.Q368K | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.184); catalogued as COSV60127052, COSV60128816; called by muse, mutect2, varscan2
- MARCO | c.1055G>C p.G352A | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59052856; called by muse, mutect2, varscan2
- MDM1 | c.1892C>G p.S631C | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.724); catalogued as COSV57444983; called by muse, mutect2, varscan2
- MED12L | c.5084G>A p.R1695Q | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as rs981287735, COSV56372585; called by muse, mutect2, varscan2
- MEF2C | c.1170C>G p.I390M | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV100426224; called by muse, mutect2
- MFAP3 | c.992C>G p.S331C | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV59455591; called by muse, mutect2, varscan2
- MFSD6L | c.175G>T p.A59S | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.555); catalogued as rs1378302730, COSV61002178; called by muse, mutect2, varscan2
- MGAM | c.4544C>G p.S1515C | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1311816325, COSV101527747, COSV72074675; called by muse, mutect2, varscan2
- MMEL1 | c.2089G>C p.E697Q | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.06); catalogued as COSV56519500; called by muse, mutect2, varscan2
- MPDZ | c.5055G>C p.L1685F | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as COSV59916197; called by muse, mutect2, varscan2
- MRC2 | c.3996G>T p.M1332I | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0.07); catalogued as COSV57637822; called by muse, mutect2, varscan2
- MROH2B | c.40G>A p.D14N | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.714); catalogued as rs1453679037, COSV68181483; called by muse, mutect2, varscan2
- MTMR12 | c.277G>C p.D93H | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.754); catalogued as COSV53783087; called by muse, mutect2, varscan2
- MUC2 | c.2267C>T p.T756M | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); catalogued as rs753827576; called by muse, mutect2, varscan2
- MUC5B | c.7706C>T p.S2569F | Missense Mutation (SNP) | VAF 48/188 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.353); catalogued as COSV71590617; called by muse, mutect2, varscan2
- MUC5B | c.7952C>G p.S2651C | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as COSV71590618; called by muse, varscan2
- MYH3 | c.5749C>G p.Q1917E | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV56862347, COSV56865081; called by muse, varscan2
- MYH3 | c.5677C>T p.H1893Y | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.023); catalogued as rs145624953; called by muse, varscan2
- MYO16 | c.3254C>T p.S1085L | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as rs200385244, COSV62747122; called by muse, mutect2, varscan2
- NCOA1 | c.1161T>A p.N387K | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.101); catalogued as COSV56041040; called by muse, mutect2, varscan2
- NDRG2 | c.623C>G p.S208C (on ENST00000298687 / NM_001354570.1; = p.S194C on NM_016250.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100069187, COSV53872034; called by muse, mutect2, varscan2
- NEK9 | c.1238C>G p.S413C | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.085); catalogued as COSV53129895; called by muse, mutect2, varscan2
- NEURL4 | c.3595G>C p.E1199Q | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.188); catalogued as COSV59748095, COSV59748826; called by muse, mutect2, varscan2
- NNMT | c.472G>C p.D158H | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749992560, COSV55473249; called by muse, mutect2, varscan2
- NNT | c.2444C>G p.S815C | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1332619258, COSV52923605; called by muse, mutect2, varscan2
- NOMO2 | c.1306C>G p.Q436E | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV57916121; called by muse, mutect2, varscan2
- NPY1R | c.835C>G p.L279V | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV56713782; called by muse, mutect2, varscan2
- NPY1R | c.418C>T p.Q140* | Nonsense Mutation (SNP) | VAF 18/68 reads (26%) | catalogued as COSV99649070; called by muse, mutect2, varscan2
- NUP107 | c.950G>A p.R317H | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs766185011, COSV57493761; called by muse, mutect2, varscan2
- NUSAP1 | c.232G>C p.E78Q | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.299); catalogued as COSV52970586; called by muse, mutect2, varscan2
- OPN5 | c.248C>T p.S83L | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as COSV55244661; called by muse, mutect2, varscan2
- OR2AT4 | c.598del p.Q200Rfs*37 | Frame Shift Del (DEL) | VAF 6/17 reads (35%) | catalogued as rs999134663; called by mutect2, varscan2
- OR6A2 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.035); catalogued as COSV60264662; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.12G>T p.E4D (on ENST00000259318 / NM_001136562.3; = p.E235D on NM_007203.5) | Missense Mutation (SNP) | VAF 4/98 reads (4%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.009); catalogued as COSV99395737; called by muse, mutect2
- PARD3 | c.2542C>T p.R848* | Nonsense Mutation (SNP) | VAF 14/44 reads (32%) | catalogued as rs1054461887, COSV100401998; called by muse, mutect2, varscan2
- PATJ | c.4258C>G p.P1420A | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as COSV56248123; called by muse, mutect2, varscan2
- PCDHA10 | c.262C>G p.R88G | Missense Mutation (SNP) | VAF 49/213 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.877); catalogued as COSV56485518, COSV56524184; called by muse, mutect2, varscan2
- PCDHA7 | c.1615G>A p.D539N | Missense Mutation (SNP) | VAF 49/171 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs782754518, COSV65342800; called by muse, mutect2, varscan2
- PCIF1 | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.67); PolyPhen benign (0.007); catalogued as COSV65026188; called by muse, mutect2, varscan2
- PDZD4 | c.823G>T p.E275* | Nonsense Mutation (SNP) | VAF 14/33 reads (42%) | catalogued as COSV99381657; called by muse, mutect2, varscan2
- PHACTR4 | c.2032G>C p.E678Q (on ENST00000373839 / NM_001350159.2; = p.E688Q on NM_023923.4) | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65783415, COSV65785417; called by muse, mutect2, varscan2
- PIGK | c.200C>G p.S67C | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV63061753, COSV63061940; called by muse, mutect2, varscan2
- PRKAB1 | c.248G>C p.R83P | Missense Mutation (SNP) | VAF 51/108 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV57554794, COSV99982478; called by muse, mutect2, varscan2
- PRR16 | c.812A>T p.H271L (on ENST00000407149 / NM_001300783.2; = p.H248L on NM_016644.2) | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0.288); catalogued as COSV65396176; called by muse, mutect2, varscan2
- PSG8 | c.711G>A p.P237= | Splice Region (SNP) | VAF 46/219 reads (21%) | catalogued as rs758446289, COSV60610447; called by muse, mutect2, varscan2
- RABGAP1L | c.358C>G p.P120A | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as rs751228276, COSV52283482, COSV99274087; called by muse, mutect2, varscan2
- RASEF | c.1148C>G p.S383C | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV64586330; called by muse, mutect2, varscan2
- RGR | c.445C>G p.L149V | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.042); catalogued as COSV63893654; called by muse, mutect2, varscan2
- RNASEH1 | c.540G>C p.Q180H | Missense Mutation (SNP) | VAF 56/217 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59438249; called by muse, mutect2, varscan2
- SAP130 | c.2721G>A p.W907* | Nonsense Mutation (SNP) | VAF 31/82 reads (38%) | catalogued as COSV99385298; called by muse, mutect2, varscan2
- SCARB2 | c.317G>A p.G106E | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.532); catalogued as COSV53668034; called by muse, mutect2, varscan2
- SDK1 | c.1994+1G>T p.X665_splice | Splice Site (SNP) | VAF 9/23 reads (39%) | catalogued as COSV67360630; called by muse, mutect2, varscan2
- SEC24B | c.2353G>C p.E785Q | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.965); catalogued as COSV54496772; called by muse, mutect2, varscan2
- SEC31B | c.1991-1G>A p.X664_splice | Splice Site (SNP) | VAF 24/50 reads (48%) | catalogued as COSV64843911; called by muse, mutect2, varscan2
- SEMA3F | c.1285G>A p.D429N | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV50028728; called by muse, mutect2, varscan2
- SH3BP4 | c.10C>G p.Q4E | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.078); catalogued as COSV60642925; called by muse, varscan2
- SIRPA | c.818G>C p.C273S | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100605399; called by muse, mutect2, varscan2
- SLC13A2 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as rs146998121, COSV58993822; called by muse, mutect2, varscan2
- SLC1A2 | c.74C>A p.S25* | Nonsense Mutation (SNP) | VAF 56/167 reads (34%) | catalogued as COSV99555043; called by muse, mutect2, varscan2
- SLC9B1 | c.470G>C p.R157T | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56468157; called by muse, mutect2, varscan2
- SMAD9 | c.1079G>A p.R360Q (on ENST00000379826 / NM_001127217.3; = p.R323Q on NM_005905.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.217); catalogued as rs777628484, COSV63204405; called by muse, mutect2, varscan2
- SMNDC1 | c.435G>C p.M145I | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0.042); catalogued as COSV63651628; called by muse, mutect2, varscan2
- SPATA4 | c.463C>G p.R155G | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.319); catalogued as rs144504100, COSV54589164; called by muse, mutect2, varscan2
- STK40 | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.81); catalogued as rs547574448, COSV63734995; called by muse, mutect2, varscan2
- SUSD1 | c.828G>T p.K276N | Missense Mutation (SNP) | VAF 95/173 reads (55%) | SIFT tolerated (0.44); PolyPhen benign (0.103); catalogued as COSV62582737; called by muse, mutect2, varscan2
- SYPL2 | c.369C>G p.I123M | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV63994758, COSV63995229; called by muse, mutect2, varscan2
- TAF1 | c.4447G>A p.D1483N (on ENST00000373790 / NM_138923.4; = p.D1504N on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV52109384; called by muse, mutect2, varscan2
- TAF7L | c.929A>G p.K310R | Missense Mutation (SNP) | VAF 63/116 reads (54%) | SIFT tolerated (0.11); PolyPhen benign (0.03); catalogued as rs774413092, COSV61256556; called by muse, mutect2, varscan2
- TAOK2 | c.2186G>A p.R729Q | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.889); catalogued as COSV54234055; called by muse, mutect2, varscan2
- TAS2R31 | c.403G>T p.G135W | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV66829999; called by muse, mutect2, varscan2
- TCF3 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.137); catalogued as rs138963927; ClinVar: uncertain significance; called by muse, varscan2
- TGM1 | c.224C>A p.S75Y | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.188); catalogued as COSV52862306; called by muse, mutect2, varscan2
- THSD7B | c.2755G>A p.E919K | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.076); catalogued as COSV55665774; called by muse, mutect2, varscan2
- TIE1 | c.1687C>T p.R563* | Nonsense Mutation (SNP) | VAF 20/57 reads (35%) | catalogued as rs749364436, COSV100992189; called by muse, mutect2, varscan2
- TNC | c.428G>A p.G143E | Missense Mutation (SNP) | VAF 69/129 reads (53%) | SIFT tolerated (0.31); PolyPhen benign (0.17); catalogued as rs1446071681, COSV60782163; called by muse, mutect2, varscan2
- TOP2B | c.1777G>C p.E593Q (on ENST00000264331 / NM_001330700.2; = p.E588Q on NM_001068.3) | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); catalogued as COSV51969961; called by muse, mutect2, varscan2
- TOX | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1412196962, COSV63844041; called by muse, mutect2, varscan2
- TRIM48 | c.51G>A p.M17I | Missense Mutation (SNP) | VAF 54/189 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as rs754486791, COSV70161112; called by muse, mutect2, varscan2
- TRIP4 | c.728C>G p.S243C | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs1420003280, COSV56029551, COSV56030124; called by muse, mutect2, varscan2
- TRMT2B | c.1126G>C p.E376Q | Missense Mutation (SNP) | VAF 45/81 reads (56%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.733); catalogued as COSV58618809; called by muse, mutect2, varscan2
- TTC30A | c.1211G>C p.R404T | Missense Mutation (SNP) | VAF 65/246 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.063); catalogued as rs555446019, COSV63100879; called by muse, mutect2, varscan2
- TTC7B | c.415C>T p.R139W | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as rs1396421458, COSV60627229; called by muse, mutect2, varscan2
- TTLL4 | c.3093C>G p.I1031M | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV51435496; called by muse, mutect2, varscan2
- UBE3A | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.298); catalogued as COSV51662755; called by muse, mutect2, varscan2
- UCP1 | c.196G>A p.V66I | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1315626973, COSV53767528; called by muse, mutect2, varscan2
- UGP2 | c.661C>A p.P221T | Missense Mutation (SNP) | VAF 40/157 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61427682; called by muse, mutect2, varscan2
- UNC119B | c.445C>G p.L149V | Missense Mutation (SNP) | VAF 82/136 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as COSV60865944; called by muse, mutect2, varscan2
- USP6 | c.510C>G p.F170L | Missense Mutation (SNP) | VAF 52/151 reads (34%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.787); catalogued as COSV51477962; called by muse, mutect2, varscan2
- UTP18 | c.532C>G p.L178V | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.729); catalogued as COSV56582655, COSV99834887; called by muse, mutect2, varscan2
- VCAN | c.2040G>C p.M680I | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV54099967; called by muse, mutect2, varscan2
- VPS13B | c.5033G>A p.R1678Q | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.992); catalogued as rs751699219, COSV62135228; called by muse, mutect2, varscan2
- WAPL | c.1768C>G p.Q590E | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0.011); catalogued as COSV53933347; called by muse, mutect2, varscan2
- ZBTB3 | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.683); catalogued as rs752303017, COSV67361011; called by muse, mutect2, varscan2
- ZBTB47 | c.1712C>T p.S571L | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as COSV51763853; called by muse, mutect2, varscan2
- ZFHX4 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.884); catalogued as rs766486497, COSV50478763, COSV50696425; called by muse, mutect2, varscan2
- ZNF318 | c.3887C>G p.S1296C | Missense Mutation (SNP) | VAF 55/193 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.443); catalogued as COSV58931150; called by muse, mutect2, varscan2
- ZNF600 | c.922G>A p.D308N | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.419); catalogued as COSV57741851, COSV57744353; called by muse, mutect2, varscan2
- ZNF646 | c.334G>T p.E112* | Nonsense Mutation (SNP) | VAF 16/50 reads (32%) | catalogued as COSV100336911; called by muse, mutect2, varscan2
- ZNF674 | c.1331G>A p.R444K | Missense Mutation (SNP) | VAF 26/41 reads (63%) | SIFT tolerated (0.3); PolyPhen benign (0.055); catalogued as COSV70378734; called by muse, mutect2, varscan2
- ZNF687 | c.1013C>G p.S338C | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs778316550, COSV55015040; called by muse, mutect2, varscan2
- ZNF831 | c.4189-1G>T p.X1397_splice | Splice Site (SNP) | VAF 14/73 reads (19%) | catalogued as rs1328598484, COSV64038450, COSV64040391; called by muse, mutect2, varscan2
- ZSWIM8 | c.4813G>C p.E1605Q (on ENST00000605216 / NM_001242487.2; = p.E1610Q on NM_015037.3) | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.003); catalogued as COSV55213368; called by muse, mutect2, varscan2
- FAM81A | c.735del p.E246Sfs*11 | Frame Shift Del (DEL) | VAF 12/54 reads (22%) | called by mutect2, pindel, varscan2
- FOXQ1 | c.362_363dup p.Y122Pfs*20 | Frame Shift Ins (INS) | VAF 19/41 reads (46%) | called by mutect2, pindel, varscan2
- HERC4 | c.971dup p.N324Kfs*26 | Frame Shift Ins (INS) | VAF 15/68 reads (22%) | called by mutect2, pindel, varscan2
- KDM6A | c.2999_3000dup p.R1001* | Frame Shift Ins (INS) | VAF 12/30 reads (40%) | called by mutect2, pindel, varscan2
- MRM1 | c.556C>G p.P186A | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- NBPF11 | c.464C>A p.A155E | Missense Mutation (SNP) | VAF 9/145 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- SEMA6A | c.921del p.R308Vfs*68 | Frame Shift Del (DEL) | VAF 22/103 reads (21%) | called by mutect2, pindel, varscan2
- ABLIM1 | c.1632C>T p.I544= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as rs759037324, COSV53302412; called by muse, mutect2, varscan2
- ACAD9 | c.1314G>A p.L438= | Silent (SNP) | VAF 46/182 reads (25%) | catalogued as COSV58306837; called by muse, mutect2, varscan2
- AFF3 | c.696C>T p.T232= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as rs375022351; called by muse, mutect2, varscan2
- APLP1 | c.1839C>A p.I613= (on ENST00000221891 / NM_001024807.3; = p.I612= on NM_005166.4) | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as rs530050323, COSV55702300, COSV55702436; called by muse, mutect2, varscan2
- ASCC3 | c.1353C>T p.L451= | Silent (SNP) | VAF 23/74 reads (31%) | catalogued as rs537210802, COSV61226715, COSV61231339; called by muse, mutect2, varscan2
- ATP2B2 | c.1998C>T p.R666= (on ENST00000352432; = p.R632= on NM_001683.5) | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as rs769370186, COSV59492084; called by muse, mutect2, varscan2
- B4GALNT1 | c.376C>T p.L126= | Silent (SNP) | VAF 101/196 reads (52%) | catalogued as COSV62041658; called by muse, mutect2, varscan2
- BAG5 | c.849C>G p.L283= | Silent (SNP) | VAF 20/112 reads (18%) | catalogued as COSV54570574; called by muse, mutect2, varscan2
- BHMT | c.90C>G p.V30= | Silent (SNP) | VAF 19/76 reads (25%) | catalogued as COSV57153828; called by muse, mutect2, varscan2
- BPTF | c.4089C>T p.L1363= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as COSV58833697; called by muse, mutect2, varscan2
- C9orf152 | c.111C>G p.L37= | Silent (SNP) | VAF 45/66 reads (68%) | catalogued as COSV68762760; called by muse, mutect2, varscan2
- CASZ1 | c.1587C>T p.F529= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as COSV59733366; called by muse, mutect2, varscan2
- CD1D | c.843G>A p.V281= | Silent (SNP) | VAF 9/71 reads (13%) | catalogued as rs1558045313, COSV63808624; called by muse, mutect2, varscan2
- CETN1 | c.243G>A p.T81= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as rs1291973143, COSV59120858, COSV59121072; called by muse, mutect2, varscan2
- CHAT | c.2163C>T p.L721= | Silent (SNP) | VAF 37/154 reads (24%) | catalogued as COSV60321908; called by muse, mutect2, varscan2
- CHGB | c.108C>T p.C36= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as COSV66759880; called by muse, mutect2, varscan2
- CHTF18 | c.1095G>A p.P365= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs776542587, COSV50103106; called by muse, mutect2
- CLTCL1 | c.1095G>A p.V365= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as COSV54226867, COSV54227083; called by muse, mutect2, varscan2
- CPA6 | c.69G>A p.K23= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as COSV52724187, COSV52728716; called by muse, mutect2, varscan2
- DEFB112 | c.213G>A p.T71= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as rs199753878; called by muse, mutect2, varscan2
- DNAJC27 | c.18G>A p.P6= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs1174258018, COSV99266760; called by muse, mutect2
- EFNB2 | c.714C>T p.F238= | Silent (SNP) | VAF 16/73 reads (22%) | catalogued as COSV55363839; called by muse, mutect2, varscan2
- EPG5 | c.5161C>T p.L1721= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as rs764123084, COSV56346599; called by muse, mutect2, varscan2
- ERC1 | c.1987C>T p.L663= (on ENST00000360905 / NM_178040.4; = p.L635= on NM_178039.4) | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as rs1484809497, COSV100705665, COSV61692778; called by muse, mutect2, varscan2
- ESRP1 | c.1203C>G p.L401= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as COSV64408442; called by muse, mutect2, varscan2
- FAT3 | c.2976C>T p.I992= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as COSV53089115, COSV53173274; called by muse, mutect2, varscan2
- FILIP1 | c.1419C>G p.V473= | Silent (SNP) | VAF 38/119 reads (32%) | catalogued as COSV52725237; called by muse, mutect2, varscan2
- FRMPD4 | c.2317C>T p.L773= | Silent (SNP) | VAF 48/89 reads (54%) | catalogued as COSV66212549; called by muse, mutect2, varscan2
- GLIS3 | c.36G>T p.R12= | Silent (SNP) | VAF 19/27 reads (70%) | catalogued as COSV67942373; called by muse, mutect2, varscan2
- HECW2 | c.1869G>A p.E623= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as rs187494430; called by muse, mutect2, varscan2
- HIF3A | c.1842G>C p.L614= (on ENST00000377670 / NM_152795.4; = p.L545= on NM_022462.4) | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as COSV52196553, COSV52200105; called by muse, mutect2, varscan2
- HINFP | c.15G>A p.G5= | Silent (SNP) | VAF 12/75 reads (16%) | catalogued as COSV63431760; called by muse, mutect2, varscan2
- IGKV3-20 | c.177G>A p.Q59= | Silent (SNP) | VAF 19/80 reads (24%) | catalogued as rs1065532; called by muse, mutect2, varscan2
- INF2 | c.1899C>G p.L633= | Silent (SNP) | VAF 39/139 reads (28%) | catalogued as rs763044552, COSV53030976; called by muse, mutect2, varscan2
- IRS4 | c.2019G>T p.V673= | Silent (SNP) | VAF 91/158 reads (58%) | catalogued as COSV64533055; called by muse, mutect2, varscan2
- KCNJ13 | c.768G>A p.L256= | Silent (SNP) | VAF 23/80 reads (29%) | catalogued as COSV52084880; called by muse, mutect2, varscan2
- KDM6B | c.1947G>A p.L649= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as rs1270862198, COSV54679174; called by muse, mutect2, varscan2
- LRP2 | c.6510G>A p.L2170= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as COSV55545920; called by muse, mutect2, varscan2
- MAGEB6B | c.123G>A p.S41= | Silent (SNP) | VAF 32/65 reads (49%) | catalogued as COSV69689609; called by muse, mutect2, varscan2
- MEFV | c.873G>A p.L291= | Silent (SNP) | VAF 30/118 reads (25%) | catalogued as COSV54819718; called by muse, mutect2
- MLIP | c.513C>T p.V171= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as rs1385920912, COSV51427491; called by muse, mutect2, varscan2
- MPP2 | c.1137G>C p.L379= (on ENST00000461854 / NM_001278372.2; = p.L355= on NM_005374.5) | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV52234309; called by muse, mutect2, varscan2
- NEU4 | c.306C>T p.F102= (on ENST00000391969 / NM_001167602.3; = p.F114= on NM_080741.4) | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV100372199; called by muse, mutect2
- PARS2 | c.1080T>C p.C360= | Silent (SNP) | VAF 17/80 reads (21%) | catalogued as COSV64883410; called by muse, mutect2, varscan2
- PAX4 | c.744G>A p.R248= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV58387960; called by muse, mutect2, varscan2
- PCDH15 | c.756A>C p.T252= | Silent (SNP) | VAF 27/111 reads (24%) | catalogued as COSV57277156; called by muse, mutect2, varscan2
- PCDHA7 | c.2229C>T p.S743= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as rs577159931, COSV65335396; called by muse, mutect2, varscan2
- PCDHGA6 | c.993G>T p.A331= | Silent (SNP) | VAF 32/117 reads (27%) | catalogued as COSV53916232; called by muse, mutect2, varscan2
- PDXDC1 | c.762G>C p.G254= | Silent (SNP) | VAF 12/85 reads (14%) | catalogued as COSV100363427; called by muse, mutect2, varscan2
- PLCH1 | c.1539C>T p.F513= (on ENST00000340059 / NM_001130960.2; = p.F525= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as rs771005375, COSV58190784; called by muse, mutect2, varscan2
- PLEC | c.13533G>T p.L4511= (on ENST00000322810 / NM_201380.4; = p.L4401= on NM_000445.5) | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as COSV59615554; called by muse, mutect2, varscan2
- POLG | c.732C>T p.L244= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as rs1446601027, COSV51520257; called by muse, mutect2, varscan2
- PRAMEF14 | c.1182G>A p.L394= | Silent (SNP) | VAF 29/134 reads (22%) | catalogued as COSV58049589; called by muse, mutect2, varscan2
- RBM42 | c.222G>C p.A74= | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as COSV52547148, COSV52550341; called by muse, mutect2, varscan2
- RIMBP2 | c.2115C>T p.D705= | Silent (SNP) | VAF 17/80 reads (21%) | catalogued as rs761677291, COSV55467808; called by muse, mutect2, varscan2
- SCAP | c.765G>A p.L255= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV55559810; called by muse, mutect2, varscan2
- SEMA5B | c.2679G>A p.V893= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as COSV52093269; called by muse, mutect2, varscan2
- SH3BP4 | c.69G>C p.L23= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as COSV60642930; called by muse, varscan2
- SLC2A5 | c.1189C>T p.L397= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV66235873; called by muse, mutect2, varscan2
- SLITRK2 | c.1620G>C p.L540= | Silent (SNP) | VAF 20/36 reads (56%) | catalogued as COSV100157474, COSV59423889; called by muse, mutect2, varscan2
- SSH2 | c.2691G>A p.K897= | Silent (SNP) | VAF 77/281 reads (27%) | catalogued as COSV52168410; called by muse, mutect2, varscan2
- SYCP2 | c.3210C>T p.V1070= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as COSV62766884; called by muse, mutect2, varscan2
- TARBP2 | c.837C>T p.L279= (on ENST00000266987 / NM_134323.2; = p.L258= on NM_004178.4) | Silent (SNP) | VAF 25/99 reads (25%) | catalogued as COSV57199236; called by muse, mutect2, varscan2
- TET3 | c.5178G>A p.E1726= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV69641362; called by muse, mutect2, varscan2
- TRPM2 | c.522C>T p.T174= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as rs763649131, COSV55967439; called by muse, mutect2, varscan2
- TSHR | c.756G>C p.L252= | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as COSV53316450; called by muse, mutect2, varscan2
- UHRF1BP1 | c.3747G>A p.L1249= | Silent (SNP) | VAF 39/61 reads (64%) | catalogued as COSV51953530; called by muse, mutect2, varscan2
- WDR72 | c.672T>G p.T224= | Silent (SNP) | VAF 26/83 reads (31%) | catalogued as COSV64743031; called by muse, mutect2, varscan2
- WNT6 | c.414C>T p.R138= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as rs750721965, COSV99293319; called by muse, varscan2
- ZNF385B | c.144C>T p.F48= | Silent (SNP) | VAF 19/74 reads (26%) | catalogued as COSV69801548; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73820974 G>A | 3'Flank (SNP) | VAF 14/33 reads (42%) | called by muse, mutect2, varscan2
- GOLGA5 | c.-1C>T | 5'UTR (SNP) | VAF 17/56 reads (30%) | catalogued as COSV99371253; called by muse, mutect2, varscan2
- IFRD2 | chr3:50292696 G>C | 5'Flank (SNP) | VAF 29/83 reads (35%) | catalogued as COSV57112946, COSV57114877; called by muse, mutect2, varscan2
- LRP5L | n.493del | RNA (DEL) | VAF 16/90 reads (18%) | called by mutect2, pindel, varscan2
- MAPK10 | c.*9G>A | 3'UTR (SNP) | VAF 24/99 reads (24%) | catalogued as COSV60378269; called by muse, mutect2, varscan2
- SLITRK2 | chrX:145827685 C>T | 3'Flank (SNP) | VAF 8/16 reads (50%) | catalogued as COSV100158208; called by muse, varscan2
- SNORD3B-2 | n.112G>A | RNA (SNP) | VAF 20/134 reads (15%) | catalogued as rs369194121; called by muse, mutect2, varscan2
- TBC1D12 | c.-1G>A | 5'UTR (SNP) | VAF 4/15 reads (27%) | catalogued as rs762145762, COSV56552290, COSV56558736; called by muse, mutect2, varscan2
